Somatic mutation profile of tumor specimen TCGA-EY-A1GF-01A (aliquot TCGA-EY-A1GF-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 75.2 years (27,450 days).
Specimen TCGA-EY-A1GF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7a0c1d2-1b18-41e5-8b0f-34af9b7a036c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GF-10A (Blood Derived Normal), aliquot TCGA-EY-A1GF-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ea2a776-448b-41c1-bcb4-9bf25db9a4b8

The open-access MAF lists 431 somatic variants for this specimen: 311 protein-altering or splice-affecting, 111 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 196, Silent 111, Frame Shift Del 73, Nonsense Mutation 18, Frame Shift Ins 11, Splice Site 5, Splice Region 4, In Frame Del 3, RNA 2, Intron 2, 5'Flank 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219del p.R74Gfs*23 | Frame Shift Del (DEL) | VAF 31/70 reads (44%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 38/88 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 16/45 reads (36%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091dup p.Y366Lfs*10 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs758946412; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 35/92 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTEN | c.959T>C p.L320S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CD110181, CM033671, CM1513166, CM992427, COSV64288766, COSV64288772, COSV64297208, COSV64305848; called by muse, mutect2, varscan2
- AASDH | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1371887051, COSV99220734; called by muse, mutect2, varscan2
- ABHD17A | c.382A>G p.S128G (on ENST00000292577 / NM_001130111.2; = p.S179G on NM_031213.4) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.201); catalogued as COSV99171200; called by muse, mutect2, varscan2
- ACSL5 | c.356G>A p.G119D (on ENST00000354273; = p.G175D on NM_016234.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100634460, COSV61130862; called by muse, mutect2, varscan2
- ACTR6 | c.497A>T p.K166I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99498467; called by muse, mutect2, varscan2
- ACVR2A | c.1373T>C p.I458T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs1490498075, COSV54021809; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- AGAP1 | c.743A>T p.N248I | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100363642, COSV58340253; called by muse, mutect2, varscan2
- AHCTF1 | c.4829A>G p.E1610G (on ENST00000366508; = p.E1584G on NM_015446.5) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV100403054; called by muse, mutect2, varscan2
- AHCY | c.694C>A p.L232M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.976); catalogued as COSV54152479, COSV99464365; called by muse, mutect2, varscan2
- AKAP4 | c.881G>T p.R294M | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV100654132; called by muse, mutect2, varscan2
- ALDH16A1 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757608462, COSV53198088; called by muse, mutect2, varscan2
- ALDH7A1 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101301983; called by muse, mutect2, varscan2
- ALK | c.3648C>T p.S1216= | Splice Region (SNP) | VAF 15/38 reads (39%) | catalogued as rs1413673953, COSV101201077; called by muse, mutect2, varscan2
- ALPP | c.617A>G p.Q206R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101235069; called by muse, mutect2
- ANGEL1 | c.1817_1819del p.F606del | In Frame Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs1188842533; called by pindel, varscan2
- ANKRD11 | c.1712C>T p.T571M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1266962947, COSV99968182; called by muse, mutect2, varscan2
- AP5Z1 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803992; called by muse, mutect2, varscan2
- APPBP2 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs1446431999, COSV99319408; called by muse, mutect2, varscan2
- ARHGEF10 | c.2470C>T p.R824* (on ENST00000398564; = p.R799* on NM_014629.4) | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as rs1297695311, COSV50653121; called by muse, mutect2, varscan2
- ARHGEF18 | c.1700G>A p.R567H (on ENST00000359920 / NM_001130955.2; = p.R463H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs779670532, COSV60471891; called by muse, mutect2, varscan2
- ARID1A | c.3461T>C p.M1154T | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs773419370, COSV100250197; called by muse, mutect2, varscan2
- ARSI | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); catalogued as rs1036095892, COSV100155872; called by muse, mutect2, varscan2
- ASNS | c.1559A>G p.Q520R | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.186); catalogued as COSV99445892; called by muse, mutect2, varscan2
- ATAD2 | c.2005C>A p.L669I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99783993; called by muse, mutect2, varscan2
- ATF7IP2 | c.487A>G p.S163G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV100202494; called by muse, mutect2, varscan2
- ATP8B4 | c.3304C>T p.R1102W | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.258); catalogued as rs749661483, COSV52713576; called by muse, mutect2, varscan2
- AXIN1 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs1266476400, COSV99249218; called by muse, mutect2, varscan2
- BACH2 | c.1615A>G p.S539G | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1478351286, COSV99997894; called by muse, mutect2, varscan2
- BRCA2 | c.7556C>A p.P2519H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101203864, COSV66449772; called by muse, varscan2
- C10orf90 | c.1951C>T p.R651* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as rs755351903, COSV52949494; called by muse, mutect2, varscan2
- C20orf194 | c.943C>G p.R315G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs757780279, COSV99330226; called by muse, mutect2, varscan2
- C3orf20 | c.2367del p.K790Sfs*9 | Frame Shift Del (DEL) | VAF 30/69 reads (43%) | catalogued as rs762124133; called by mutect2, pindel, varscan2
- CACNA1F | c.3863C>A p.S1288Y | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs782046813, COSV100544326; called by muse, mutect2, varscan2
- CANX | c.914A>G p.D305G | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99910181; called by muse, mutect2, varscan2
- CAPRIN1 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs763872104, COSV100403489; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC88C | c.4004A>G p.N1335S | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs761981033, COSV101105061; called by muse, mutect2, varscan2
- CDK5 | c.55T>C p.F19L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV99876630; called by mutect2, varscan2
- CEBPG | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99392707; called by muse, mutect2, varscan2
- CEP350 | c.7382C>A p.P2461H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100854285; called by muse, mutect2, varscan2
- CHMP4B | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.302); catalogued as COSV99459598; called by muse, mutect2, varscan2
- CHRM3 | c.1700dup p.R568Efs*26 | Frame Shift Ins (INS) | VAF 14/52 reads (27%) | catalogued as rs751548647; called by mutect2, varscan2
- CLCN2 | c.2068del p.E690Rfs*6 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | catalogued as rs765672654; called by mutect2, pindel, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 16/37 reads (43%) | catalogued as rs369752219; called by mutect2, varscan2
- COL6A1 | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.061); catalogued as COSV100719881; called by muse, mutect2, varscan2
- COPA | c.2729del p.P910Qfs*38 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as COSV54102261; called by mutect2, pindel, varscan2
- CROCC | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 38/210 reads (18%) | catalogued as rs766907213, COSV100978040; called by muse, mutect2
- CRX | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs142111462, COSV55759068; called by muse, mutect2, varscan2
- CRYGB | c.251del p.P84Rfs*8 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as rs1559328208, COSV53679868; called by mutect2, pindel
- CSMD3 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs774621721, COSV52136673; called by muse, mutect2, varscan2
- CTSB | c.821T>A p.M274K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.29); PolyPhen benign (0.054); catalogued as COSV100565794; called by muse, mutect2, varscan2
- CYP19A1 | c.310T>A p.F104I | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV99547234; called by muse, mutect2, varscan2
- DDB1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100074235; called by muse, mutect2, varscan2
- DENND4B | c.4336G>A p.V1446M | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1249215268, COSV100768363; called by muse, mutect2, varscan2
- DENND4B | c.1735A>G p.K579E | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV100768364; called by muse, mutect2, varscan2
- DENND5B | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1416680550, COSV60909833; called by muse, mutect2, varscan2
- DHX34 | c.2601C>T p.D867= | Splice Region (SNP) | VAF 26/55 reads (47%) | catalogued as rs374857096; called by muse, mutect2, varscan2
- DLG5 | c.4442del p.P1481Qfs*88 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs778796396, CM066561; called by mutect2, pindel, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 9/16 reads (56%) | catalogued as rs761292636; called by mutect2, varscan2
- DNASE2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761957135, COSV99262226; called by muse, mutect2, varscan2
- DOK3 | c.50A>G p.H17R | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV100394190; called by muse, mutect2, varscan2
- DOK4 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1277329947, COSV54673701; called by muse, mutect2, varscan2
- EFEMP1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100816717; called by muse, mutect2, varscan2
- ELK3 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866414172, COSV99957464; called by muse, mutect2, varscan2
- EML2 | c.849C>A p.N283K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as COSV99839515, COSV99839681; called by muse, mutect2
- ENOX2 | c.51C>T p.A17= | Splice Region (SNP) | VAF 22/42 reads (52%) | catalogued as rs748847026, COSV100583726, COSV57649613; called by muse, mutect2, varscan2
- EPHA3 | c.2478G>T p.W826C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60698957, COSV60715910; called by muse, mutect2, varscan2
- EPHB4 | c.1954G>A p.G652S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs950348363, COSV100639393; called by muse, mutect2, varscan2
- ERN1 | c.2801C>T p.T934I | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV101458370; called by muse, mutect2, varscan2
- ETV1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.169); catalogued as rs536563766, COSV54142227; called by muse, mutect2, varscan2
- EXOC6 | c.1947T>G p.H649Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as rs1231394506, COSV99591369; called by muse, mutect2, varscan2
- EYS | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | catalogued as COSV100675614; called by muse, mutect2, varscan2
- FAM133A | c.193dup p.M65Nfs*3 | Frame Shift Ins (INS) | VAF 10/27 reads (37%) | catalogued as rs760026337; called by mutect2, pindel, varscan2
- FAM13B | c.1562C>A p.S521* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99220931; called by muse, mutect2, varscan2
- FANCD2 | c.1661A>G p.D554G | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99810248; called by muse, mutect2, varscan2
- FAT2 | c.3154A>T p.I1052F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV99941541; called by muse, mutect2, varscan2
- FBN3 | c.1803dup p.L602Afs*64 | Frame Shift Ins (INS) | VAF 17/42 reads (40%) | catalogued as rs772353703; called by mutect2, varscan2
- FBXW5 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99812310; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2036T>G p.I679S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.637); catalogued as COSV100435424; called by muse, mutect2, varscan2
- FRAS1 | c.821G>T p.C274F | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99347897; called by muse, mutect2, varscan2
- GAL | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as rs970169359, COSV99681827; called by muse, mutect2, varscan2
- GCA | c.627+2T>C p.X209_splice | Splice Site (SNP) | VAF 23/70 reads (33%) | catalogued as rs751997369, COSV99280402; called by muse, mutect2, varscan2
- GIGYF1 | c.331dup p.L111Pfs*20 | Frame Shift Ins (INS) | VAF 8/18 reads (44%) | catalogued as rs763147690; called by mutect2, varscan2
- GIMAP1 | c.655C>A p.H219N | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.664); catalogued as COSV100211916; called by muse, mutect2, varscan2
- GNA11 | c.477-1G>A p.X159_splice | Splice Site (SNP) | VAF 21/59 reads (36%) | catalogued as COSV50018041; called by muse, mutect2, varscan2
- GNE | c.2240A>G p.Y747C (on ENST00000396594 / NM_001128227.3; = p.Y716C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV100929876; called by mutect2, varscan2
- GREB1 | c.2372C>T p.S791L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs775792701, COSV99302141; called by muse, mutect2, varscan2
- GTF2IRD1 | c.320del p.G107Afs*26 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as COSV99734322; called by mutect2, pindel, varscan2
- GTF3C3 | c.1081del p.T361Lfs*26 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs750792116; called by mutect2, varscan2
- GTSE1 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs139655645; called by muse, mutect2
- GUSB | c.476_477insA p.P161Afs*31 | Frame Shift Ins (INS) | VAF 21/85 reads (25%) | catalogued as COSV100512491; called by mutect2, pindel, varscan2
- GZF1 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754196028, COSV57636257; called by muse, mutect2, varscan2
- HAS1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99708196; called by muse, mutect2, varscan2
- HDGFL2 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV56681182; called by muse, mutect2, varscan2
- HEATR3 | c.1600-2A>T p.X534_splice | Splice Site (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99589733; called by muse, mutect2, varscan2
- HIVEP3 | c.4727C>T p.T1576M | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs377345320; called by muse, mutect2, varscan2
- HK3 | c.2377C>A p.L793I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99457754; called by muse, mutect2, varscan2
- HSPA8 | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV99914153; called by muse, mutect2, varscan2
- IARS2 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.697); catalogued as COSV100228060; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 22/31 reads (71%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INTS7 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100877364; called by muse, mutect2, varscan2
- IQSEC1 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs751783194, COSV99831235; called by muse, mutect2, varscan2
- IRF9 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 32/64 reads (50%) | catalogued as COSV100138027; called by muse, mutect2, varscan2
- ITGAX | c.1843A>G p.T615A | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as COSV51648776; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV101198133; called by muse, mutect2, varscan2
- KBTBD6 | c.200T>G p.I67S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV101068687; called by muse, mutect2, varscan2
- KCNA6 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 17/104 reads (16%) | catalogued as COSV99768293; called by muse, mutect2, varscan2
- KCNH5 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.103); catalogued as COSV100525215; called by muse, mutect2, varscan2
- KIAA1549 | c.3946G>A p.V1316I | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0.068); catalogued as COSV99649665; called by muse, mutect2, varscan2
- KIF5C | c.2679C>A p.D893E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as COSV101276089; called by muse, mutect2, varscan2
- KMT2D | c.15541G>T p.G5181W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977209; called by muse, mutect2, varscan2
- KMT2D | c.14809C>T p.P4937S | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV99977210; called by muse, mutect2, varscan2
- KMT2E | c.1165C>A p.H389N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.76); catalogued as COSV99995730; called by muse, mutect2, varscan2
- KPNA6 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs746123297, COSV101012431; called by muse, mutect2, varscan2
- KRT17 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs750279151, COSV100245036; called by muse, mutect2, varscan2
- KRTAP10-4 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV100551730; called by muse, mutect2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs775423572; called by mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 31/58 reads (53%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LRRC39 | c.684G>A p.W228* | Nonsense Mutation (SNP) | VAF 29/53 reads (55%) | catalogued as COSV100734319; called by muse, mutect2, varscan2
- LRRC41 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs775910871, COSV58441063; called by muse, mutect2, varscan2
- LRRC41 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100586069; called by muse, mutect2
- LUZP1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.7); PolyPhen benign (0.053); catalogued as rs544676272, COSV56498725; called by muse, mutect2, varscan2
- MAN2B2 | c.2488C>A p.L830I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV99576906; called by muse, mutect2
- MAP3K1 | c.3857_3859del p.E1286del | In Frame Del (DEL) | VAF 11/23 reads (48%) | catalogued as rs1397309724; called by pindel, varscan2
- MARCKSL1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV100269476; called by muse, mutect2
- MCM5 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99331436; called by muse, mutect2
- MDP1 | c.242T>G p.L81R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99164586; called by muse, mutect2, varscan2
- ME3 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs1366280240, COSV100041989; called by muse, mutect2, varscan2
- MIER1 | c.1060C>G p.P354A (on ENST00000355356 / NM_001077701.3; = p.P371A on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100590785; called by muse, mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | catalogued as rs750307488; called by mutect2, varscan2
- MNS1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV99549353; called by muse, mutect2, varscan2
- MSH6 | c.1644T>A p.D548E | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV99314967; called by muse, mutect2, varscan2
- MTERF1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs752117598, COSV100699533; called by muse, mutect2, varscan2
- MTM1 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV100080143; called by muse, mutect2, varscan2
- MYBPC3 | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as CM152770, CS111328, COSV99919824; called by muse, mutect2, varscan2
- MYH1 | c.1282G>T p.G428C | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99874793; called by muse, mutect2, varscan2
- MYOM3 | c.994G>T p.V332L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.88); PolyPhen benign (0.349); catalogued as rs1557613494, COSV100292391; called by muse, mutect2, varscan2
- NASP | c.478del p.T160Qfs*29 | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | catalogued as COSV100601638; called by mutect2, pindel, varscan2
- NAV1 | c.3968A>G p.D1323G | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99818116; called by muse, mutect2, varscan2
- NCKAP5L | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV100258273; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs747914168; called by mutect2, varscan2
- NECTIN1 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV99871734; called by muse, mutect2, varscan2
- NEK2 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.685); catalogued as rs1211179624, COSV100878721, COSV65357583; called by mutect2, varscan2
- NFE2 | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.69); catalogued as COSV100380669; called by muse, mutect2, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NOD2 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1409767769, COSV56050472; called by mutect2, varscan2
- NPC1L1 | c.3433C>A p.L1145I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.06); catalogued as COSV99202577; called by muse, mutect2, varscan2
- NQO1 | c.679A>G p.S227G | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV100276541; called by muse, mutect2, varscan2
- NR3C2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.159); catalogued as COSV100678627; called by muse, mutect2, varscan2
- NUMBL | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.134); catalogued as rs1047593516, COSV99424687; called by muse, mutect2, varscan2
- NVL | c.2234_2237del p.F745Wfs*13 | Frame Shift Del (DEL) | VAF 35/123 reads (28%) | catalogued as rs765634292; called by mutect2, pindel, varscan2
- OR10J5 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV100604606; called by muse, mutect2, varscan2
- OR2G6 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV100598017; called by muse, mutect2, varscan2
- OXNAD1 | c.359T>A p.L120Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99551028; called by muse, mutect2, varscan2
- PACS2 | c.1889C>T p.T630M | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs376311769; called by muse, mutect2, varscan2
- PAX4 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs114416157; called by muse, mutect2, varscan2
- PCDHA2 | c.2295del p.K766Rfs*29 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | catalogued as rs558931090, COSV65368078; called by mutect2, pindel, varscan2
- PCDHGC4 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99337641; called by muse, mutect2, varscan2
- PCLO | c.11025G>T p.M3675I | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV100427040; called by muse, mutect2, varscan2
- PCNX4 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.692); catalogued as COSV100469855; called by muse, mutect2, varscan2
- PCSK5 | c.1909G>T p.D637Y | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100949423; called by muse, varscan2
- PDCD11 | c.3103A>G p.I1035V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as COSV100874229; called by muse, mutect2, varscan2
- PEX5 | c.1877G>A p.R626Q (on ENST00000420616; = p.R618Q on NM_000319.5) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as rs762252851, COSV99870659; called by muse, mutect2, varscan2
- PHACTR1 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as COSV60672515; called by muse, mutect2, varscan2
- PHF12 | c.776A>G p.H259R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs768884258, COSV99255416; called by muse, mutect2, varscan2
- PHF20L1 | c.2078G>A p.G693D | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.257); catalogued as COSV99620247; called by muse, mutect2, varscan2
- PKP2 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV99297165; called by muse, mutect2, varscan2
- PLAC8 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100274427; called by muse, mutect2, varscan2
- PLCG2 | c.1376G>C p.G459A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.999); catalogued as COSV100842034; called by muse, mutect2, varscan2
- PLEKHH2 | c.3059T>C p.I1020T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs756202189, COSV99174298; called by muse, mutect2, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs772701630; called by mutect2, varscan2
- PNMA2 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV101580582, COSV72908458; called by muse, mutect2, varscan2
- POU2F2 | c.954G>A p.A318= (on ENST00000526816 / NM_001207025.3; = p.A302= on NM_002698.5) | Splice Region (SNP) | VAF 15/31 reads (48%) | catalogued as COSV60764728; called by muse, mutect2, varscan2
- PPP1R14C | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100744829, COSV63173202; called by muse, mutect2, varscan2
- PRKAG1 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100304845; called by muse, mutect2, varscan2
- PRRC2C | c.3625C>T p.R1209C (on ENST00000367742; = p.R1207C on NM_015172.4) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769267279, COSV58904732; called by muse, mutect2, varscan2
- PRX | c.1568T>C p.L523P | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs550446238, COSV52528043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSD2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as rs201061729; called by mutect2, varscan2
- PSD2 | c.920G>A p.C307Y | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.363); catalogued as COSV51198026, COSV99216978; called by mutect2, varscan2
- PTEN | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746152219, CM1513163, COSV64296809, COSV64296832; ClinVar: uncertain significance; called by muse, varscan2
- PTH1R | c.959A>T p.Y320F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as COSV100480768; called by muse, mutect2, varscan2
- PWP1 | c.1041_1042del p.R347Sfs*17 | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | catalogued as rs765444638; called by pindel, varscan2
- PYCR2 | c.854C>A p.T285N | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV100661472; called by muse, mutect2, varscan2
- QPRT | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99568873; called by muse, mutect2, varscan2
- RAI1 | c.2069C>A p.P690H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs573550712, COSV99883242; called by mutect2, varscan2
- RELCH | c.1633del p.L545Sfs*25 | Frame Shift Del (DEL) | VAF 60/165 reads (36%) | catalogued as COSV99902226; called by mutect2, pindel, varscan2
- RELN | c.4508T>A p.I1503N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.182); catalogued as COSV100632226; called by muse, mutect2, varscan2
- RGS22 | c.3393G>A p.W1131* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as rs1305099800, COSV100692960; called by muse, mutect2, varscan2
- RO60 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as rs201998409, COSV66473229; called by muse, mutect2, varscan2
- ROBO1 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1375295913, COSV71395455; called by muse, mutect2, varscan2
- ROBO3 | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs369554878; called by muse, mutect2, varscan2
- RORC | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1427978992, COSV100561782; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RS1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1800002, COSV101183689; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- SALL3 | c.3790C>T p.R1264C | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs146109999; called by muse, mutect2, varscan2
- SCAP | c.1775C>T p.T592M | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.719); catalogued as COSV99652370; called by muse, mutect2, varscan2
- SEC16A | c.2418G>T p.Q806H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99255967; called by muse, mutect2, varscan2
- SERPINA4 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV100096915; called by muse, mutect2, varscan2
- SERPINB2 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100208156; called by muse, mutect2, varscan2
- SERPINE1 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV56171994, COSV99776567; called by muse, mutect2, varscan2
- SLC12A5 | c.3305G>A p.R1102H (on ENST00000454036 / NM_001134771.2; = p.R1079H on NM_020708.5) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99275135; called by muse, mutect2, varscan2
- SLC18A3 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100339660; called by muse, mutect2, varscan2
- SLC20A2 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100645988; called by muse, mutect2, varscan2
- SLC22A9 | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV99654686; called by muse, mutect2, varscan2
- SLC25A28 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.806); catalogued as rs375360825; called by muse, mutect2, varscan2
- SLC6A11 | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144692520; called by muse, mutect2, varscan2
- SLC6A15 | c.1868T>C p.V623A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs780689417, COSV99880110; called by muse, mutect2, varscan2
- SLC6A18 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs144208211; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 37/40 reads (93%) | catalogued as rs763364024; called by mutect2, varscan2
- SNAP91 | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99534203; called by muse, mutect2, varscan2
- SNX8 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as rs754455290, COSV56126158; called by muse, mutect2, varscan2
- SOX7 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV100448954; called by muse, mutect2, varscan2
- SPTBN2 | c.4388C>T p.S1463L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.479); catalogued as rs768355416, COSV59457167; called by muse, mutect2, varscan2
- SRFBP1 | c.707dup p.N236Kfs*5 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs751748506; called by mutect2, varscan2
- SSTR1 | c.1126G>A p.G376S | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV99942673; called by muse, mutect2, varscan2
- ST18 | c.1862del p.N621Ifs*10 | Frame Shift Del (DEL) | VAF 37/82 reads (45%) | catalogued as rs1563701552; called by mutect2, varscan2
- STIP1 | c.829A>T p.K277* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as COSV100534777; called by muse, mutect2, varscan2
- STOML2 | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.904); catalogued as COSV100521166; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2966G>A p.G989E | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV100561424; called by muse, mutect2, varscan2
- STYXL2 | c.1094T>C p.V365A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99608522; called by muse, mutect2, varscan2
- SUMO3 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100254292; called by muse, mutect2, varscan2
- SV2A | c.412del p.E138Rfs*39 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | catalogued as rs1553764068; called by mutect2, varscan2
- TAF1L | c.1906C>T p.R636C | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144278499; called by muse, mutect2, varscan2
- TANGO6 | c.1751A>G p.H584R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99935592; called by muse, mutect2, varscan2
- TANK | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV99375808; called by muse, mutect2
- TBC1D8 | c.1727T>C p.V576A | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1200697770, COSV100964255; called by muse, mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 10/17 reads (59%) | catalogued as rs756457255; called by mutect2, varscan2
- TELO2 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99247986; called by muse, mutect2, varscan2
- TENM2 | c.3940A>G p.K1314E (on ENST00000518659 / NM_001122679.2; = p.K1075E on NM_001080428.3) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV101317720; called by muse, mutect2, varscan2
- TEP1 | c.5566del p.V1856Lfs*45 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs746695887; called by mutect2, pindel, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as COSV50235787; called by mutect2, pindel, varscan2
- TPCN1 | c.2281C>T p.R761* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100136363; called by muse, mutect2, varscan2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | catalogued as rs770561785; called by mutect2, varscan2
- TRIM3 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100624214; called by muse, mutect2, varscan2
- TTC38 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV66843761; called by muse, mutect2, varscan2
- TTC7B | c.1872T>A p.D624E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.978); catalogued as COSV100127195; called by muse, mutect2, varscan2
- TTF1 | c.479A>G p.H160R | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100524430, COSV57507679; called by muse, mutect2, varscan2
- TTN | c.32113C>T p.R10705* (on ENST00000591111; = p.R9778* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/75 reads (47%) | catalogued as rs747806875, COSV59995211; called by muse, mutect2, varscan2
- UNC79 | c.3955G>A p.D1319N (on ENST00000393151 / NM_001346218.2; = p.D1142N on NM_020818.5) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.284); catalogued as rs867652626, COSV99825574; called by muse, mutect2, varscan2
- USP10 | c.1250T>C p.L417P | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99551097; called by muse, mutect2, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 26/63 reads (41%) | catalogued as rs773064295, COSV51967888; called by mutect2, pindel, varscan2
- WDR1 | c.1543G>T p.V515L (on ENST00000382452; = p.V375L on NM_005112.5) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV101221063; called by muse, mutect2, varscan2
- WDR41 | c.1101del p.F367Lfs*35 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as rs748110033; called by mutect2, pindel, varscan2
- WDR86 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs774752569, COSV57837824; called by muse, mutect2, varscan2
- XKR7 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs966669267, COSV73813539; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | catalogued as rs762052135; called by mutect2, varscan2
- ZCCHC12 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100038393; called by muse, mutect2, varscan2
- ZDHHC16 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV100620481; called by muse, varscan2
- ZNF282 | c.254T>C p.M85T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as COSV100021381; called by muse, mutect2, varscan2
- ZNF292 | c.3317C>T p.T1106I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867081943, COSV100369683; called by muse, mutect2, varscan2
- ZNF366 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as rs748522840, COSV59214371; called by muse, mutect2
- ZNF407 | c.5768G>A p.S1923N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.193); catalogued as COSV100224527; called by muse, mutect2, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs780189754; called by mutect2, pindel, varscan2
- ZNF683 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780459912, COSV62873486; called by muse, varscan2
- ZNF70 | c.792C>A p.S264R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.222); catalogued as COSV100558818; called by muse, mutect2, varscan2
- ZNF782 | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs1350586937, COSV100001109; called by muse, mutect2, varscan2
- AFF4 | c.2064del p.R689Gfs*28 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.2949del p.K983Nfs*4 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- ARHGAP36 | c.92del p.L31* | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- ATG16L1 | c.1709del p.K570Rfs*66 (on ENST00000392017 / NM_030803.7; = p.K551Rfs*66 on NM_017974.4) | Frame Shift Del (DEL) | VAF 39/98 reads (40%) | called by mutect2, pindel, varscan2
- BAZ1A | c.1092dup p.E365Rfs*7 | Frame Shift Ins (INS) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- BDP1 | c.1971del p.D658Ifs*3 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- CPLX1 | c.65del p.G22Vfs*73 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- DGAT2L6 | c.766del p.I256Sfs*4 | Frame Shift Del (DEL) | VAF 34/86 reads (40%) | called by mutect2, pindel, varscan2
- DST | c.10242del p.L3415* | Frame Shift Del (DEL) | VAF 23/56 reads (41%) | called by mutect2, pindel, varscan2
- FNBP1 | c.983dup p.N328Kfs*2 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | called by mutect2, varscan2
- GABRD | c.1241del p.G414Afs*95 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- GBP1 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2
- GEMIN4 | c.1874del p.L625* | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- GMIP | c.2773del p.L925Cfs*104 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- GNAS | c.1058del p.P353Qfs*337 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- GNB4 | c.403_405del p.V135del | In Frame Del (DEL) | VAF 13/27 reads (48%) | called by mutect2, pindel, varscan2
- IQCH | c.2222del p.X741_splice | Splice Site (DEL) | VAF 12/27 reads (44%) | called by mutect2, pindel, varscan2
- ITFG1 | c.1578del p.K526Nfs*17 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 40/48 reads (83%) | called by mutect2, varscan2
- KANK4 | c.248dup p.A84Cfs*31 | Frame Shift Ins (INS) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- KASH5 | c.836del p.K279Rfs*13 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- KIAA0319L | c.2723C>A p.P908H | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- KIF7 | c.1709del p.G570Vfs*29 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- KMO | c.1259del p.K420Rfs*2 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.4211_4212del p.E1404Vfs*15 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by pindel, varscan2
- MAP3K20 | c.665del p.N222Tfs*4 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, varscan2
- MRC1 | c.2279C>A p.P760H | Missense Mutation (SNP) | VAF 9/264 reads (3%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.729); called by muse, mutect2
- MYOCD | c.684del p.S229Afs*4 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- NEDD4L | c.606del p.V203Wfs*4 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- OR5AR1 | c.312del p.F104Lfs*2 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- ORC2 | c.145del p.I49* | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | called by mutect2, pindel, varscan2
- ORM1 | c.604T>C p.*202Qext*? | Nonstop Mutation (SNP) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- PIK3C2B | c.2154del p.S719Afs*29 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
- POLR1B | c.2353del p.I785Lfs*23 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- PQBP1 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.237); called by muse, mutect2
- PTPN5 | c.1409del p.P470Hfs*56 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- RCBTB2 | c.298del p.I100* | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- RNF43 | c.784del p.S262Qfs*157 | Frame Shift Del (DEL) | VAF 23/32 reads (72%) | called by mutect2, pindel, varscan2
- SHISA3 | c.695G>T p.C232F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); called by muse, mutect2
- TBC1D24 | c.1529del p.X510_splice (on ENST00000646147 / NM_001199107.2; = p.X504_splice on NM_020705.3) | Splice Site (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- TBX19 | c.1175del p.P392Lfs*22 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- TM9SF3 | c.1212del p.F404Lfs*6 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | called by mutect2, pindel, varscan2
- TRIM21 | c.1367del p.N456Tfs*5 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- UTP14C | c.1463_1464del p.E488Gfs*36 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by pindel, varscan2
- VPS8 | c.1941del p.K647Nfs*2 (on ENST00000625842 / NM_001349294.1; = p.K645Nfs*2 on NM_015303.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- XRCC2 | c.810del p.F270Lfs*27 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- XRCC2 | c.350del p.L117Wfs*17 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | called by mutect2, varscan2
- ZMYM3 | c.591_592del p.E197Dfs*17 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | called by pindel, varscan2
- ZNF484 | c.1129del p.I377Ffs*23 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- ABI3BP | c.1692G>A p.T564= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs549391660, COSV99425192; called by muse, mutect2, varscan2
- AKAP12 | c.3486G>A p.S1162= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV53571371; called by muse, mutect2, varscan2
- ARID1B | c.4101C>T p.Y1367= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs377021700, COSV99269138; ClinVar: uncertain significance; called by muse, mutect2
- ARID5A | c.723G>A p.R241= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100673519; called by muse, mutect2, varscan2
- BRD4 | c.933G>A p.P311= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs775880214, COSV99649881; called by muse, mutect2, varscan2
- C2CD3 | c.3531G>T p.V1177= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV100486203; called by muse, mutect2, varscan2
- CACNA1F | c.93G>A p.G31= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV100544327; called by muse, mutect2, varscan2
- CARTPT | c.102G>A p.Q34= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99703896; called by muse, mutect2, varscan2
- CDSN | c.207T>C p.S69= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99456604; called by muse, mutect2, varscan2
- CKMT2 | c.39T>C p.N13= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99562239; called by muse, mutect2, varscan2
- CLCN1 | c.2010G>A p.R670= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as rs1335125543, COSV100577665; called by muse, mutect2, varscan2
- CLEC4D | c.414G>A p.R138= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100222877; called by muse, mutect2, varscan2
- CLUH | c.3219C>T p.F1073= (on ENST00000435359; = p.F1112= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs1378995491, COSV101425613; called by muse, mutect2, varscan2
- CPED1 | c.1911A>G p.L637= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1465654947, COSV100119906; called by muse, mutect2, varscan2
- CXCR1 | c.741C>T p.V247= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs150187869; called by muse, mutect2, varscan2
- CXXC4 | c.837C>T p.D279= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs1487176167, COSV67296168; called by muse, mutect2, varscan2
- DHX36 | c.828A>G p.V276= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100273267; called by muse, mutect2, varscan2
- DPYSL4 | c.252A>G p.T84= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100633811; called by muse, mutect2, varscan2
- EPHA8 | c.594C>T p.R198= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs915435424, COSV99384103; called by muse, mutect2, varscan2
- FAM120A | c.2340C>A p.A780= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV99464389; called by muse, mutect2, varscan2
- FAM47C | c.1788G>A p.P596= | Silent (SNP) | VAF 60/143 reads (42%) | catalogued as rs1556332793, COSV100792257; called by muse, mutect2, varscan2
- FBN3 | c.3177C>T p.Y1059= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs375976165; called by muse, mutect2, varscan2
- FBXO31 | c.921T>C p.G307= | Silent (SNP) | VAF 110/249 reads (44%) | catalogued as rs1294359731, COSV100291236; called by muse, mutect2, varscan2
- G6PC2 | c.354C>T p.G118= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs185108752, COSV56371540; called by muse, mutect2, varscan2
- GABRQ | c.1353C>T p.S451= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs372512790, COSV64783036; called by muse, mutect2, varscan2
- GAPVD1 | c.2553G>A p.S851= (on ENST00000394104; = p.S878= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs1357728460, COSV52921013; called by mutect2, varscan2
- GATA1 | c.426C>T p.S142= | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as COSV100936668; called by muse, mutect2, varscan2
- GOLGA6B | c.1830G>A p.V610= | Silent (SNP) | VAF 35/215 reads (16%) | catalogued as COSV101406895; called by muse, mutect2, varscan2
- GPRIN3 | c.1668C>A p.T556= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs767649789, COSV100310559; called by muse, mutect2, varscan2
- GTDC1 | c.948C>T p.H316= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs370764973; called by muse, mutect2, varscan2
- HAX1 | c.192C>T p.G64= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs11556340, COSV99670481; called by muse, mutect2, varscan2
- HECTD4 | c.7980C>T p.D2660= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs1305039737, COSV101106649; called by muse, mutect2, varscan2
- HIP1 | c.2814C>A p.A938= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV100416873; called by muse, mutect2, varscan2
- HPN | c.684C>T p.H228= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs766906590, COSV52882283; called by muse, mutect2, varscan2
- IFT172 | c.2682C>T p.R894= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs1411173138, COSV99561692; called by muse, mutect2, varscan2
- IKZF4 | c.6T>C p.H2= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV56269403; called by muse, mutect2, varscan2
- INHBB | c.1002C>T p.G334= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV99735598; called by muse, mutect2, varscan2
- KCNH6 | c.357C>T p.D119= | Silent (SNP) | VAF 68/80 reads (85%) | catalogued as rs770846582, COSV59003000; called by muse, mutect2, varscan2
- KCNT1 | c.2655C>T p.N885= (on ENST00000488444; = p.N904= on NM_020822.3) | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs554237279, COSV53710340; ClinVar: likely benign; called by muse, mutect2, varscan2
- KMT2A | c.11283C>T p.H3761= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs371289157, COSV63286230; ClinVar: likely benign; called by muse, mutect2, varscan2
- KMT2C | c.543T>C p.Y181= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV100065951; called by muse, mutect2, varscan2
- KRTAP20-2 | c.57C>T p.G19= | Silent (SNP) | VAF 94/209 reads (45%) | catalogued as rs1194592664, COSV58182517; called by muse, mutect2, varscan2
- LMOD2 | c.72C>T p.S24= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV101505402; called by muse, mutect2, varscan2
- LRRC8B | c.1038C>A p.S346= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as COSV100446409; called by muse, mutect2, varscan2
- LSM3 | c.126A>G p.R42= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99542042; called by muse, mutect2, varscan2
- MAPK6 | c.141C>G p.A47= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV99958838; called by muse, mutect2, varscan2
- MAPK9 | c.6C>T p.S2= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs779045924, COSV100558081; called by muse, mutect2, varscan2
- MAST4 | c.7641G>A p.R2547= (on ENST00000403625 / NM_001164664.2; = p.R2358= on NM_015183.3) | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV99842676; called by muse, mutect2, varscan2
- MDC1 | c.4377C>A p.T1459= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as COSV64529755; called by muse, mutect2, varscan2
- MEIS2 | c.372G>A p.A124= (on ENST00000561208 / NM_170675.5; = p.A111= on NM_002399.3) | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV54943329, COSV99575675; called by muse, mutect2, varscan2
- MFGE8 | c.348C>T p.A116= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs758934827, COSV99183934; called by muse, mutect2, varscan2
- MIB2 | c.1341C>T p.D447= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs555571273; called by muse, mutect2
- MMP12 | c.396C>T p.Y132= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs199918414; called by muse, mutect2, varscan2
- MOB2 | c.129G>A p.L43= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100326433; called by muse, mutect2, varscan2
- MTG2 | c.513C>T p.A171= | Silent (SNP) | VAF 30/49 reads (61%) | catalogued as rs981532922, COSV63694363; called by muse, mutect2, varscan2
- MTTP | c.705A>T p.T235= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs746679400, COSV99644721; called by muse, mutect2, varscan2
- MUC16 | c.16692C>A p.T5564= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV101197943, COSV67496248; called by muse, mutect2, varscan2
- MUC6 | c.3606G>A p.P1202= | Silent (SNP) | VAF 72/159 reads (45%) | catalogued as rs1366753802, COSV70145317; called by muse, mutect2, varscan2
- MUS81 | c.1053G>A p.E351= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100337157; called by muse, mutect2, varscan2
- MYH10 | c.3021C>T p.R1007= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99343959; called by muse, mutect2, varscan2
- MYOF | c.606C>G p.R202= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV100825158, COSV100826053; called by muse, mutect2
- NAV1 | c.3268C>T p.L1090= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV99818114; called by muse, mutect2, varscan2
- NBEAL2 | c.5859T>C p.T1953= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV99434268; called by muse, mutect2, varscan2
- NEK2 | c.76C>A p.R26= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs370861680, COSV100878504; called by muse, mutect2, varscan2
- NENF | c.231C>T p.S77= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as rs773299463, COSV65341197; called by muse, mutect2, varscan2
- NPM1 | c.681C>T p.S227= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs1386690228, COSV51559410, COSV99741467; called by muse, mutect2, varscan2
- NTAN1 | c.282C>T p.D94= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs143783591; called by muse, mutect2, varscan2
- NTN5 | c.168C>T p.G56= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as rs773395245, COSV54307833; called by muse, mutect2, varscan2
- NTRK1 | c.2307G>A p.Q769= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100693113; called by muse, mutect2
- OAF | c.639C>A p.P213= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100202839; called by muse, mutect2, varscan2
- OR2G6 | c.891G>A p.V297= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100598018; called by muse, mutect2, varscan2
- OTUB1 | c.687G>A p.V229= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99734567; called by muse, mutect2, varscan2
- PADI3 | c.1632G>A p.V544= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as rs1308535740, COSV100968382; called by muse, mutect2, varscan2
- PAFAH2 | c.606C>T p.V202= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100959197; called by muse, mutect2, varscan2
- PCDHA3 | c.1170G>A p.T390= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as rs782105993, COSV63539377; called by muse, mutect2, varscan2
- PCDHA6 | c.1533C>T p.H511= | Silent (SNP) | VAF 16/191 reads (8%) | catalogued as rs781943283, COSV65345598, COSV65346836; called by muse, mutect2
- PCDHAC1 | c.648C>T p.D216= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1376391756, COSV53838511; called by muse, mutect2, varscan2
- PELI1 | c.192G>A p.Q64= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100735045; called by muse, mutect2, varscan2
- PGGT1B | c.423A>G p.R141= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99685831; called by muse, mutect2, varscan2
- PIK3CD | c.2217C>A p.T739= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2
- PLA2G3 | c.942T>C p.H314= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99311280; called by muse, mutect2, varscan2
- PLXNA1 | c.1887G>A p.T629= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs376837581; called by muse, mutect2, varscan2
- RAPGEF5 | c.1617T>A p.T539= (on ENST00000401957 / NM_001367602.2; = p.T842= on NM_012294.5) | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100686388; called by muse, mutect2, varscan2
- RBP3 | c.2118C>T p.G706= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs782605269; called by muse, mutect2, varscan2
- RBPJL | c.1314C>T p.D438= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as COSV59213964; called by muse, mutect2, varscan2
- RPN1 | c.99T>C p.N33= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs764417908, COSV99956843; called by muse, mutect2, varscan2
- RUNX3 | c.687C>A p.P229= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as rs1220482457, COSV100136625; called by muse, mutect2
- SATL1 | c.1254C>T p.Y418= (on ENST00000395409; = p.Y605= on NM_001012980.2) | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs976389081, COSV100260657; called by muse, mutect2, varscan2
- SIRPA | c.657C>T p.R219= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as rs756429332, COSV61537450; called by muse, mutect2, varscan2
- SLC25A32 | c.879C>T p.C293= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV52569374, COSV99884176; called by muse, mutect2, varscan2
- SLC66A1 | c.717C>T p.P239= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs568274566, COSV100913157, COSV100913160; called by muse, mutect2, varscan2
- SLC9A5 | c.4C>T p.L2= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99263786; called by muse, mutect2, varscan2
- SLCO2A1 | c.1386T>C p.N462= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs1360435556, COSV100188631; called by muse, mutect2, varscan2
- SPHKAP | c.2559C>T p.C853= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV100763649; called by muse, mutect2, varscan2
- SS18L2 | c.91C>T p.L31= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV99165265; called by muse, mutect2, varscan2
- STAB2 | c.819A>G p.Q273= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV101185595; called by muse, mutect2
- SYK | c.1422G>T p.L474= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV101002253; called by muse, mutect2, varscan2
- SYNPO | c.2388C>T p.N796= (on ENST00000394243 / NM_001166208.2; = p.N552= on NM_007286.6) | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs138232729; called by muse, mutect2, varscan2
- TLN2 | c.2364G>A p.V788= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100167908; called by muse, mutect2, varscan2
- TMBIM6 | c.552C>T p.F184= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs771055193; called by muse, mutect2, varscan2
- TMED9 | c.456T>C p.Y152= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs913409567, COSV100215438; called by mutect2, varscan2
- TRPC3 | c.1443C>T p.F481= (on ENST00000379645 / NM_001366479.2; = p.F408= on NM_003305.2) | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs756019751, COSV53376656; called by muse, mutect2, varscan2
- TUBA3E | c.798C>T p.H266= | Silent (SNP) | VAF 40/210 reads (19%) | catalogued as COSV99919609; called by muse, mutect2
- TYMS | c.690C>T p.Y230= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs202044096, COSV51890836; called by muse, mutect2, varscan2
- VPS28 | c.87C>T p.N29= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as rs1434170440, COSV99465365; called by muse, mutect2, varscan2
- WNT11 | c.516C>T p.S172= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as rs1488213535, COSV59444682; called by muse, mutect2, varscan2
- WNT2 | c.1035G>A p.V345= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99625675; called by muse, mutect2, varscan2
- WWTR1 | c.324G>A p.Q108= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs778949810, COSV100640782; called by muse, varscan2
- YEATS2 | c.2517C>T p.G839= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV59368649; called by muse, mutect2, varscan2
- ZNF609 | c.318T>A p.T106= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100440318; called by muse, mutect2, varscan2
- ZNF768 | c.1239G>A p.R413= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs766006975, COSV100776038; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840535 C>T | 5'Flank (SNP) | VAF 33/70 reads (47%) | catalogued as COSV58339261; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851997 A>G | 3'Flank (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501820 del CTT | 5'Flank (DEL) | VAF 22/62 reads (35%) | catalogued as rs757619804; called by pindel, varscan2
- B4GALNT1 | c.*1159A>G | 3'UTR (SNP) | VAF 19/35 reads (54%) | catalogued as COSV100246912; called by muse, mutect2, varscan2
- NBPF25P | n.744A>C | RNA (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- POLA1 | c.2947-21467G>A | Intron (SNP) | VAF 29/60 reads (48%) | catalogued as rs974626510, COSV66888059; called by muse, mutect2, varscan2
- SHC1 | c.1624-224G>A | Intron (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- TEX2 | chr17:64146379 del G | 3'Flank (DEL) | VAF 11/38 reads (29%) | catalogued as rs751261074; called by mutect2, pindel, varscan2
- WASF4P | n.1305C>A | RNA (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
